TCGA case TCGA-BQ-7058 — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3cad2139-0bc5-4c8f-994a-018be7e2e6ea

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 81 years; Vital status: Dead; Days to death: 343 days.

Diagnoses (5)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 81.7 years (29,856 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC clinical T: T3a; AJCC clinical N: N1; AJCC clinical M: M0; AJCC clinical stage: Stage III; AJCC pathologic T: T3; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 8; Prcc type: Type 2.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sorafenib; Days to treatment start: 203 days; Days to treatment end: 216 days; Prescribed dose: 800; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sorafenib; Days to treatment start: 216 days; Days to treatment end: 295 days; Prescribed dose: 400; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temsirolimus; Initial disease status: Progressive Disease; Days to treatment start: 302 days; Days to treatment end: 302 days; Prescribed dose: 25; Prescribed dose units: mg; Route of administration: Intravenous.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Prostate gland; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Androgen Deprivation Therapy (ADT); Treatment anatomic sites: Locoregional Site.
3. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: External ear; Classification of tumor: Prior primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 81.9 years (29,906 days); Days to diagnosis: 50 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
5. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 82.5 years (30,151 days); Days to diagnosis: 295 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.

Follow-up (3 entries)
- Day 50 (post initial treatment): Progression or recurrence: Yes.
- Day 295 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 343 days; Disease response: With Tumor.

Molecular and laboratory tests
- Calcium: Low.
- Hemoglobin: Low.
- Platelets: Normal.
- Leukocytes: Elevated.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 74.4 kg; Height: 178 cm; BMI: 23.5.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BQ-7058-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.9; Intermediate dimension: 0.9; Shortest dimension: 0.2.
  Slide TCGA-BQ-7058-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-BQ-7058-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BQ-7058-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BQ-7058-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 0.4; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Serum calcium level: Low; Hemoglobin level: Low; Lymph nodes examined: Yes; Tobacco smoking history indicator: 1.
- Drug treatment 1: Regimen number: 3; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 2; Therapy regimen: OTHER, SPECIFY IN NOTES.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 3: Regimen number: 1; Therapy regimen: OTHER, SPECIFY IN NOTES.
- Follow-up form 1: Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Ear.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form 2, Drug treatment: Pharmaceutical therapy extent: Locoregional.
- Other malignancy form 2, Drug treatment, Administered drug: Pharmaceutical therapy drug name: Adrogen deprivation therapy.
- Other malignancy form 2, Radiation treatment: Radiation therapy extent: Locoregional.

GDC annotations on this case (curator notes; quoted as recorded):
- History of acceptable prior treatment related to a prior/other malignancy: Prior malignancy skin cancer. No systemic chemotherapy or radiation. Prior malignancy prostate cancer treated with locoregional androgen deprivation therapy and locoregional radiation.
- Prior malignancy: Prior malignancy skin cancer. No systemic chemotherapy or radiation. Prior malignancy prostate cancer treated with locoregional androgen deprivation therapy and locoregional radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 343 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 343 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 50 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BQ-7058-01A-11D-1959-01): tumor purity 0.83, ploidy 2.02, whole-genome doublings 0.
